Somatic mutation profile of tumor specimen TCGA-CD-5798-01A (aliquot TCGA-CD-5798-01A-11D-1600-08) from TCGA case TCGA-CD-5798, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 83.0 years (30,310 days).
Specimen TCGA-CD-5798-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a142a6e9-54c7-4d54-9318-33b9c6176908.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-5798-10A (Blood Derived Normal), aliquot TCGA-CD-5798-10A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d26867f-b49f-44a0-a39b-ab5a1b5a8402

The open-access MAF lists 87 somatic variants for this specimen: 61 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 24, RNA 2, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 5/53 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ABAT | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); catalogued as rs778229930, COSV51622239; called by muse, mutect2
- ACACB | c.1354A>T p.M452L | Missense Mutation (SNP) | VAF 72/669 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV58132496; called by muse, mutect2, varscan2
- ATM | c.6453-1G>A p.X2151_splice | Splice Site (SNP) | VAF 18/164 reads (11%) | catalogued as CD053525, COSV53738831, COSV53765303; called by muse, mutect2, varscan2
- ATP6V1D | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as rs773197310, COSV53599326; called by muse, mutect2, varscan2
- ATXN7L3 | c.809G>T p.S270I (on ENST00000389384 / NM_001382309.1; = p.S277I on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV60228651; called by muse, mutect2, varscan2
- BLK | c.10G>C p.V4L | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs151045602, COSV52051144; called by muse, mutect2, varscan2
- CDK9 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.9); catalogued as rs1246168747, COSV64723681; called by muse, mutect2
- CDR1 | c.714T>G p.I238M | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as COSV65164121; called by muse, mutect2, varscan2
- CFAP46 | c.8044G>A p.V2682I | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs769349617, COSV99585118; called by muse, mutect2
- CKAP5 | c.2806A>C p.K936Q | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV56366846; called by muse, mutect2
- CNR1 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs768033952, COSV100759232, COSV62986936; called by muse, mutect2, varscan2
- COPG1 | c.1726C>T p.L576F | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.203); catalogued as COSV59113644; called by muse, mutect2
- CTNND2 | c.3167C>T p.T1056M | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774846850, COSV58861894, COSV58874369; called by muse, mutect2, varscan2
- CXCR5 | c.1080_1083del p.E362Qfs*39 | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | catalogued as rs781445622; called by mutect2, pindel
- CYP7B1 | c.1380A>C p.K460N | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59586538; called by muse, mutect2
- DCAF12L1 | c.856T>G p.F286V | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV64421509; called by muse, mutect2, varscan2
- DCLK1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs1340568626, COSV55173920; called by muse, mutect2, varscan2
- DESI2 | c.314A>G p.H105R | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as COSV55640825; called by muse, mutect2
- DNAH11 | c.2127C>A p.F709L | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs746839370, COSV60951986, COSV60981348; called by muse, mutect2, varscan2
- DNAJC2 | c.408C>G p.D136E | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50790095; called by muse, mutect2
- ECM1 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV60872542; called by muse, mutect2
- EGLN2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as COSV58279723; called by muse, mutect2
- EPB41L3 | c.1117G>T p.A373S | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1401046522, COSV59450599; called by muse, mutect2, varscan2
- EPRS1 | c.1450G>T p.V484F | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100859416; called by muse, mutect2
- EPS8 | c.1961T>A p.I654K | Missense Mutation (SNP) | VAF 38/319 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.093); catalogued as COSV55529694; called by muse, mutect2, varscan2
- FLRT2 | c.1106T>G p.L369R | Missense Mutation (SNP) | VAF 23/240 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.043); catalogued as rs779901780, COSV58139920; called by muse, mutect2
- GABRG2 | c.1159T>G p.F387V (on ENST00000361925 / NM_001375343.1; = p.F347V on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62717290; called by muse, mutect2
- GPAM | c.2092G>A p.G698R | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV62080808; called by muse, mutect2
- IGLV3-25 | c.121T>A p.C41S | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs769248639; called by muse, mutect2
- ITGA4 | c.571T>A p.F191I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs775360380, COSV51999469; called by muse, mutect2, varscan2
- KCTD10 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57326601, COSV99949181; called by muse, mutect2, varscan2
- LPIN1 | c.2597C>T p.T866I | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs767988183, COSV56764551; called by muse, mutect2, varscan2
- LRFN5 | c.963T>G p.I321M | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV53252404; called by muse, mutect2, varscan2
- LRP4 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.953); catalogued as rs1285042004, COSV66135313; called by muse, mutect2, varscan2
- MFSD9 | c.940T>G p.F314V | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51493242; called by muse, mutect2, varscan2
- NIPAL2 | c.586C>T p.L196F | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV57839432, COSV57841508; called by muse, mutect2
- OR5T2 | c.46C>A p.H16N | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.037); catalogued as COSV57588720, COSV57591177; called by muse, mutect2
- PCDHA9 | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs782711616, COSV65323184; called by muse, mutect2
- PCDHAC2 | c.404A>T p.E135V | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV53846171; called by muse, mutect2, varscan2
- PCDHGA5 | c.1448A>G p.D483G | Missense Mutation (SNP) | VAF 28/307 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); catalogued as rs375101471; called by muse, mutect2
- PRSS35 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs186993743, COSV63800436, COSV63801045; called by muse, mutect2
- PXDN | c.2672C>T p.S891L | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53231925, COSV99412151; called by muse, mutect2
- RBBP7 | c.826A>C p.N276H | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV58112779; called by muse, mutect2, varscan2
- SACS | c.7990G>A p.G2664R | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66538530; called by muse, mutect2
- SHMT2 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 10/99 reads (10%) | catalogued as rs758199349, COSV61073220; called by muse, mutect2, varscan2
- SLC9A3 | c.2257G>C p.D753H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV53800546; called by muse, varscan2
- STIM1 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs199914458, COSV56153860; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TARBP1 | c.1218G>T p.K406N | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV50182726, COSV50213115; called by muse, mutect2, varscan2
- TAS2R9 | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53688624; called by muse, mutect2, varscan2
- TDP2 | c.588T>G p.I196M | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV61966920; called by muse, mutect2
- TMEM132D | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.382); catalogued as rs749019418, COSV70601176; called by muse, mutect2, varscan2
- TNRC6A | c.3981A>T p.R1327S | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV59363213; called by muse, mutect2, varscan2
- TRAF3 | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 24/272 reads (9%) | catalogued as COSV61024890; called by muse, mutect2
- TTN | c.94576G>A p.D31526N (on ENST00000591111; = p.D24102N on NM_003319.4) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | PolyPhen probably damaging (0.999); catalogued as COSV59996099; called by muse, mutect2
- XDH | c.2941C>T p.R981W | Missense Mutation (SNP) | VAF 35/306 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775019798, COSV65148170; called by muse, mutect2, varscan2
- ZFYVE16 | c.959G>A p.R320K | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV62015365; called by muse, mutect2, varscan2
- ZNF33A | c.2096A>C p.K699T (on ENST00000458705 / NM_006974.3; = p.K700T on NM_006954.2) | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56724403; called by muse, mutect2
- ZNF585A | c.1459A>C p.T487P (on ENST00000292841 / NM_001288800.2; = p.T432P on NM_152655.3) | Missense Mutation (SNP) | VAF 29/289 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV53063009; called by muse, mutect2, varscan2
- ZNF598 | c.2544C>G p.N848K | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV50192186; called by muse, mutect2
- ERCC6L | c.2568_2569del p.L857Afs*9 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- C1QC | c.519G>A p.S173= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as rs777173734, COSV65889494; called by muse, mutect2, varscan2
- EPB41L3 | c.2415G>A p.A805= | Silent (SNP) | VAF 44/472 reads (9%) | catalogued as rs1200791161, COSV100550817, COSV59444169; called by muse, mutect2
- FHIT | c.93G>T p.V31= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100534724; called by muse, mutect2
- FZD3 | c.735C>T p.Y245= | Silent (SNP) | VAF 21/219 reads (10%) | catalogued as COSV53535179; called by muse, mutect2, varscan2
- IGHV3-16 | c.153T>C p.S51= | Silent (SNP) | VAF 34/338 reads (10%) | called by muse, mutect2, varscan2
- IRAK1 | c.474C>T p.L158= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs200612880, COSV57653231; called by muse, mutect2, varscan2
- KLF12 | c.639G>A p.P213= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as rs571821638, COSV66569233; called by muse, mutect2
- MAP3K19 | c.813G>A p.S271= | Silent (SNP) | VAF 23/176 reads (13%) | catalogued as rs772166646, COSV59638066; called by muse, mutect2, varscan2
- NCSTN | c.1624C>T p.L542= | Silent (SNP) | VAF 15/154 reads (10%) | catalogued as COSV54186961; called by muse, mutect2, varscan2
- NMS | c.456G>A p.Q152= | Silent (SNP) | VAF 4/86 reads (5%) | catalogued as COSV65258531; called by muse, mutect2
- NOTCH2 | c.651C>T p.Y217= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as rs150410907; called by muse, mutect2, varscan2
- NRXN3 | c.204T>C p.P68= | Silent (SNP) | VAF 24/308 reads (8%) | catalogued as COSV99819889; called by muse, mutect2
- PCDHB15 | c.1857G>A p.A619= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as rs1217877580, COSV50865650; called by muse, mutect2
- PLXNC1 | c.1131A>T p.T377= | Silent (SNP) | VAF 27/205 reads (13%) | catalogued as COSV51573744; called by muse, mutect2
- RUNX2 | c.961C>T p.L321= | Silent (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- SMAP2 | c.1173G>A p.Q391= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV65531980; called by muse, mutect2
- TADA1 | c.267C>T p.S89= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as rs141542819; called by muse, mutect2
- TMEM132D | c.1431A>G p.E477= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV70601736; called by muse, mutect2
- TTN | c.47688A>G p.G15896= (on ENST00000591111; = p.G8472= on NM_003319.4) | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV59996127; called by muse, mutect2
- TUBA3E | c.687C>A p.R229= | Silent (SNP) | VAF 12/292 reads (4%) | catalogued as COSV56058800; called by muse, mutect2
- VIT | c.1680C>T p.N560= (on ENST00000389975 / NM_001177969.1; = p.N575= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as rs368776924; called by muse, mutect2
- ZNF285 | c.201G>A p.S67= | Silent (SNP) | VAF 21/248 reads (8%) | catalogued as rs73557001; called by muse, mutect2
- ZNF345 | c.255T>A p.T85= | Silent (SNP) | VAF 10/145 reads (7%) | catalogued as COSV59323676; called by muse, mutect2
- ZSCAN18 | c.1116G>A p.P372= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs1188796745, COSV53732247; called by muse, mutect2
- C8orf86 | n.741C>T | RNA (SNP) | VAF 12/142 reads (8%) | catalogued as COSV63935262; called by muse, mutect2
- UBTFL2 | n.488T>A | RNA (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
